Gene-level copy-number profile of tumor specimen TCGA-MP-A4TJ-01A from TCGA case TCGA-MP-A4TJ, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.6 years (22,875 days).
Specimen TCGA-MP-A4TJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.46285202-b19f-4f78-8394-fcd1d48eabd3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MP-A4TJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/a62a76e9-b9be-41b5-8be3-126633fd0012

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 19,535; copy number 2: 32,394; copy number 3: 7,042; copy number 4: 799; copy number 29: 35; copy number 30: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 45 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:23,185,316–23,882,428, 35 genes, copy number 29 (within-gene range 2–29): RNF212B, AL049829.1, RNU6-1046P, HOMEZ, H3P37, PPP1R3E, BCL2L2, BCL2L2-PABPN1, PABPN1, SLC22A17, EFS, AL049829.2, IL25, CMTM5, MYH6, MIR208A, MYH7, AL132855.1, MIR208B, NGDN, ZFHX2-AS1, ZFHX2, AL135999.2, THTPA, AP1G2, AL135999.1, JPH4, AL135999.3, DHRS2, AL160237.1, BRD7P1, AL160237.3, RN7SKP205, AL160237.2, AL136419.2.
- chr14:26,208,036–27,295,516, 10 genes, copy number 30 (within-gene range 2–30): CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.

Autosomal genes at a single copy (total copy number 1): 17,918. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
